TARGET case TARGET-40-PALPAX — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00888d4f-8eca-55e5-914e-5a76315f396c

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 1,037 days (2.8 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 15.9 years (5,792 days); Year of diagnosis: 2002; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 1,037 days (2.8 years); Sites of involvement: Bone, NOS.
   Pathology details: Necrosis percent: 60.
   Treatment given: Protocol identifier: AOST0121.

Follow-up (2 entries)
- Days to follow up: 292 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 292 days; Days to first event: 292 days; First event: Relapse.
- Days to follow up: 1,037 days (2.8 years); Year of follow up: 2005.

Biospecimens (1 sample)
- Sample TARGET-40-PALPAX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PALPAX-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: no

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PALPAX-01A - 02:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 50
- % Non Tumor Nuclei: Top from Biopsy: 50
- % Cellular Tumor: Top from Biopsy: 44
- % Normal: Top from Biopsy: 55
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 1
- % Tumor Nuclei: Bottom from Biopsy: 50
- % Non Tumor Nuclei: Bottom from Biopsy: 50
- % Cellular Tumor: Bottom from Biopsy: 69
- % Normal: Bottom from Biopsy: 30
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 1
- PASS/FAIL: fail

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1037
- Disease at diagnosis: Metastatic (confirmed)
- Metastasis site: Bone only
- Primary tumor site: Arm/hand
- Specific tumor site: Humerus
- Definitive Surgery: Limb sparing
- Site of initial relapse: Lung
